FM case AD843 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/132c6a8d-0471-4a5a-bd18-6adc5807fd05

Male, 46.4 years: diagnosis not reported by GDC of the biliary tract; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
